Somatic mutation profile of tumor specimen C3N-00551-04 (aliquot CPT0067940006) from CPTAC case C3N-00551, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 54.7 years (19,986 days).
Specimen C3N-00551-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bed702e4-0e9c-41f7-a410-86b3660b1d21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00551-71 (Blood Derived Normal), aliquot CPT0068030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c78e3a8b-058d-465b-8018-e29f2ebf8b11

The open-access MAF lists 717 somatic variants for this specimen: 499 protein-altering or splice-affecting, 132 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 436, Silent 132, Intron 40, Nonsense Mutation 27, RNA 14, Splice Site 13, 3'UTR 12, Frame Shift Del 11, 5'UTR 9, 3'Flank 7, Frame Shift Ins 5, Splice Region 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 96/301 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs782159028, COSV54387281; called by muse, mutect2, varscan2
- ACVR2B | c.1016A>T p.D339V | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61701797; called by muse, mutect2, varscan2
- ADGRV1 | c.14614G>T p.A4872S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV101315716; called by muse, mutect2, varscan2
- AKT3 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV55606144, COSV99794347, COSV99796240; called by muse, mutect2, varscan2
- ALMS1 | c.8029G>T p.D2677Y | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100044081; called by muse, mutect2, varscan2
- APBA1 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99597229; called by muse, mutect2, varscan2
- APOD | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752071105; called by muse, mutect2
- ATP10B | c.1397C>A p.T466N | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV58777691; called by muse, varscan2
- BBS9 | c.2137G>A p.V713M (on ENST00000242067 / NM_001348036.1; = p.V673M on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/509 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.264); catalogued as rs1048975482; called by muse, mutect2
- BCAS1 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 122/337 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV65090342; called by muse, mutect2, varscan2
- BFSP1 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64900195; called by muse, mutect2, varscan2
- BMP7 | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 185/555 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101216167; called by muse, mutect2, varscan2
- C1orf141 | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100924388; called by muse, mutect2, varscan2
- CA8 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs781229474; called by muse, mutect2, varscan2
- CAMSAP1 | c.2056G>T p.G686C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs904244949; called by muse, mutect2, varscan2
- CDH11 | c.1894G>T p.V632F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV51771673; called by muse, mutect2
- CDH22 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 75/501 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765974679; called by muse, mutect2, varscan2
- CDH22 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64838158; called by muse, mutect2, varscan2
- CDH24 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52975589; called by muse, mutect2, varscan2
- CDH4 | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64648404; called by muse, mutect2, varscan2
- CEP89 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201497197; called by muse, mutect2, varscan2
- CHST1 | c.981C>A p.H327Q | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs1187230633; called by muse, varscan2
- CLN6 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 129/488 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); catalogued as COSV51116277; called by muse, mutect2, varscan2
- COL11A1 | c.2656-1G>T p.X886_splice | Splice Site (SNP) | VAF 32/486 reads (7%) | catalogued as COSV62201787; called by muse, mutect2
- COL11A2 | c.3068C>T p.A1023V (on ENST00000341947 / NM_080680.3; = p.A916V on NM_080679.2) | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.399); catalogued as rs755840773; called by muse, mutect2, varscan2
- COL6A6 | c.1958A>T p.Q653L | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV62024341; called by muse, mutect2, varscan2
- CPB1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV51576571; called by muse, mutect2, varscan2
- CPOX | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51637544; called by muse, mutect2, varscan2
- CR1 | c.39del p.P14Rfs*44 | Frame Shift Del (DEL) | VAF 44/288 reads (15%) | catalogued as COSV65458820; called by mutect2, pindel, varscan2
- DNAJC13 | c.3164G>A p.C1055Y | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1443724009; called by muse, mutect2, varscan2
- DSG4 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV57395189; called by muse, mutect2, varscan2
- DYTN | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373862091; called by muse, mutect2
- EFCAB6 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs140051719; called by muse, mutect2, varscan2
- EP300 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 72/453 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.375); catalogued as rs774675956, COSV54335035; called by muse, mutect2, varscan2
- ESPNL | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV58032070; called by muse, mutect2
- EXOC1L | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404132781; called by muse, mutect2
- FAM135B | c.2318C>A p.A773D | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52749817; called by muse, mutect2, varscan2
- FAM135B | c.628T>G p.L210V | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as rs1451908736, COSV52703427, COSV52706446; called by muse, mutect2
- FAM47B | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs202142258, COSV61456638; called by muse, mutect2, varscan2
- FREM1 | c.2384T>C p.I795T | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs1474230129; called by muse, mutect2
- FRMD6 | c.688G>T p.A230S (on ENST00000344768 / NM_001267046.2; = p.A222S on NM_152330.4) | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs374236968; called by muse, mutect2, varscan2
- GABRA6 | c.318G>T p.L106F | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.961); catalogued as COSV50884051; called by muse, mutect2, varscan2
- GABRE | c.345A>G p.E115= | Splice Region (SNP) | VAF 24/61 reads (39%) | catalogued as rs1351515352; called by muse, mutect2, varscan2
- GABRQ | c.1447C>A p.R483S | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as rs782062554, COSV64781816; called by muse, mutect2, varscan2
- GINS3 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1215376636; called by muse, mutect2
- GRM2 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV56583584; called by muse, mutect2, varscan2
- HOXC12 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV54534494; called by muse, mutect2, varscan2
- IGKV2D-30 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 59/498 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs376925419; called by muse, mutect2, varscan2
- IL1R2 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60205804, COSV60210082; called by muse, mutect2
- ITGB3 | c.939+1G>T p.X313_splice | Splice Site (SNP) | VAF 68/316 reads (22%) | catalogued as rs987869733; called by muse, mutect2, varscan2
- ITGB6 | c.885G>T p.L295F | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299690741; called by muse, mutect2, varscan2
- IVD | c.794-1G>C p.X265_splice (on ENST00000651168; = p.X262_splice on NM_002225.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 122/420 reads (29%) | catalogued as CS001433; called by muse, mutect2, varscan2
- KCNA4 | c.1873A>G p.K625E | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.017); catalogued as rs762878567; called by muse, mutect2, varscan2
- KCNN1 | c.904C>A p.R302S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as COSV55838947; called by mutect2, varscan2
- KDM4D | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.766); catalogued as COSV58633658; called by muse, mutect2, varscan2
- KDR | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761405036, COSV55777162; called by muse, mutect2, varscan2
- KERA | c.719C>A p.A240D | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs776712179; called by muse, mutect2, varscan2
- KIF2B | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs370500459, COSV52134588; called by muse, mutect2, varscan2
- KLRC4 | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs1310311704; called by muse, mutect2, varscan2
- LAMA5 | c.2242G>T p.A748S | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.696); catalogued as COSV53372012; called by muse, mutect2, varscan2
- LBH | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143197806; called by muse, mutect2, varscan2
- LCOR | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV100603588; called by muse, mutect2
- LRP1B | c.11934G>T p.W3978C | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs769840715; called by muse, mutect2, varscan2
- MAP1A | c.7376C>T p.P2459L | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs745568582; called by muse, mutect2, varscan2
- MARF1 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780016235, COSV100705682; called by muse, mutect2, varscan2
- MDN1 | c.798G>T p.R266S | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1392523319; called by muse, mutect2, varscan2
- MEF2D | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV61730116; called by muse, varscan2
- MMEL1 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs1036872724; called by muse, mutect2, varscan2
- MMP28 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as rs1000026322; called by muse, mutect2
- MRTFB | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100371317; called by muse, mutect2, varscan2
- MUC16 | c.34619C>A p.P11540H | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs762304924; called by muse, mutect2, varscan2
- MUC16 | c.6917G>A p.G2306E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs754130128; called by muse, mutect2, varscan2
- MUC19 | c.451G>T p.G151* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as rs1450608793; called by muse, mutect2, varscan2
- MYH7 | c.2347C>A p.R783S | Missense Mutation (SNP) | VAF 72/441 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as COSV100805719; called by muse, mutect2, varscan2
- MYH8 | c.2955G>T p.M985I | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV101238962; called by muse, mutect2, varscan2
- MYT1L | c.2636+1G>C p.X879_splice | Splice Site (SNP) | VAF 17/164 reads (10%) | catalogued as CS1211517; called by muse, mutect2, varscan2
- NBPF12 | c.1620C>G p.N540K | Missense Mutation (SNP) | VAF 64/501 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1222718780; called by muse, mutect2, varscan2
- NEU2 | c.754G>T p.G252W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52092667; called by mutect2, varscan2
- NEURL1B | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV100874834; called by muse, mutect2, varscan2
- NHS | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs770236873, COSV66273190; ClinVar: benign; called by muse, mutect2, varscan2
- NINL | c.4127C>T p.A1376V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs760971731; called by muse, mutect2, varscan2
- NRG3 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.943); catalogued as rs1200356642; called by muse, mutect2, varscan2
- OOEP | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV64859287; called by muse, mutect2
- OR10G2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1314019209, COSV73390436; called by muse, mutect2, varscan2
- OR14I1 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs767063023, COSV61199263, COSV61199290; called by muse, mutect2, varscan2
- OR1C1 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV68715614; called by muse, mutect2, varscan2
- OR1D5 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1213845331, COSV73859510; called by muse, mutect2, varscan2
- OR4C13 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV73648736; called by muse, mutect2
- OR5F1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1256694310, COSV99558936; called by muse, varscan2
- OR5F1 | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV53546406; called by muse, varscan2
- OR8B2 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66664714; called by muse, mutect2, varscan2
- PARP6 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1182348617, COSV53003092; called by muse, mutect2
- PCDH15 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV100229911, COSV57285609; called by muse, mutect2
- PDZRN3 | c.1441C>A p.R481S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV55198103; called by muse, mutect2, varscan2
- PEAR1 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404312516; called by muse, mutect2, varscan2
- PKHD1 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 87/572 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100581816; called by muse, mutect2, varscan2
- PKHD1L1 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199692519; called by muse, mutect2
- PLEC | c.7868A>T p.Q2623L (on ENST00000322810 / NM_201380.4; = p.Q2513L on NM_000445.5) | Missense Mutation (SNP) | VAF 161/549 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs782783768; called by muse, mutect2, varscan2
- PLOD2 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV51466277; called by muse, mutect2, varscan2
- POLR2A | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs776597121; called by muse, mutect2
- PPP1R13L | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.319); catalogued as rs969532493, COSV62907787; called by muse, mutect2
- PPP3CC | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51501775; called by muse, mutect2
- PRDM9 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99031450; called by muse, mutect2, varscan2
- PRPF19 | c.421A>C p.I141L | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1337220082; called by muse, mutect2, varscan2
- PRR30 | c.172C>A p.R58S | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs553610498; called by muse, mutect2, varscan2
- PRR35 | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV53463538; called by muse, mutect2, varscan2
- PRR9 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100907323; called by muse, mutect2
- PSME4 | c.2278G>T p.G760W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101122618; called by muse, mutect2
- RELL2 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1194162874; called by muse, mutect2
- RGSL1 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs184518879, COSV54262381; called by muse, mutect2, varscan2
- RPS6KA2 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 25/112 reads (22%) | catalogued as COSV99691751; called by muse, mutect2, varscan2
- RRH | c.909G>C p.R303S | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100496243; called by muse, mutect2, varscan2
- RSF1 | c.2926A>G p.I976V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs776593351; called by muse, mutect2, varscan2
- RTN1 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | catalogued as COSV99957128; called by muse, mutect2, varscan2
- SALL3 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV73306040; called by muse, mutect2
- SCAF11 | c.3935A>G p.N1312S | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs1237853967, COSV101014386; called by muse, mutect2, varscan2
- SCNN1B | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 94/417 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV100225468; called by muse, mutect2, varscan2
- SEC24B | c.2164A>G p.T722A | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as COSV54501512; called by muse, mutect2
- SETD1B | c.1688G>T p.R563L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs942845427, COSV57354408; called by muse, mutect2, varscan2
- SF3B5 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV62451528; called by muse, mutect2, varscan2
- SIGLEC1 | c.3588C>G p.D1196E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV52458231; called by muse, mutect2
- SLC12A5 | c.2062C>A p.P688T (on ENST00000454036 / NM_001134771.2; = p.P665T on NM_020708.5) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as rs1357044095, COSV54802806; called by muse, mutect2, varscan2
- SLC17A2 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs776445761, COSV55350281; called by muse, mutect2, varscan2
- SLC17A2 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1171827935; called by muse, varscan2
- SLC6A19 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 68/776 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58670788; called by muse, mutect2
- SNAPC4 | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs1264059820; called by muse, mutect2, varscan2
- SORCS1 | c.1940+1G>A p.X647_splice | Splice Site (SNP) | VAF 11/127 reads (9%) | catalogued as rs1447669165, COSV53872995; called by muse, mutect2
- SORL1 | c.1106G>C p.R369P | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV52750819; called by muse, mutect2
- SOWAHA | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as rs763068818, COSV66332346; called by muse, mutect2, varscan2
- SPAG17 | c.3993C>A p.H1331Q | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.483); catalogued as COSV100310672; called by muse, mutect2
- ST8SIA5 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 42/298 reads (14%) | PolyPhen benign (0.13); catalogued as COSV59331795; called by muse, mutect2, varscan2
- TAS2R16 | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV50798761; called by muse, mutect2, varscan2
- TCF7L2 | c.547A>G p.I183V (on ENST00000355995 / NM_001367943.1; = p.I160V on NM_030756.5) | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.842); catalogued as rs143077353; called by muse, mutect2, varscan2
- TMCC2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as rs531333872, COSV58003505; called by muse, mutect2
- TMEM132C | c.1018C>A p.R340S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1002960609, COSV59430003; called by muse, varscan2
- TMEM132C | c.2941C>A p.L981M | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59436401; called by muse, mutect2, varscan2
- TNFRSF4 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99767646; called by mutect2, varscan2
- TNRC6B | c.5233G>A p.G1745R (on ENST00000454349 / NM_001162501.2; = p.G1635R on NM_015088.3) | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427240135; called by muse, mutect2, varscan2
- TP53 | c.837del p.R280Efs*65 | Frame Shift Del (DEL) | VAF 147/714 reads (21%) | catalogued as CD963012, COSV53098982, COSV53696473; called by mutect2, pindel, varscan2
- TSC1 | c.107-1G>T p.X36_splice | Splice Site (SNP) | VAF 80/381 reads (21%) | catalogued as COSV53774238; called by muse, mutect2, varscan2
- TUBA3C | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV101262840, COSV67138997; called by muse, mutect2, varscan2
- UBN2 | c.1997G>T p.S666I | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV56034006; called by muse, mutect2, varscan2
- UGT2B28 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV59432526; called by muse, mutect2, varscan2
- USH2A | c.9949C>T p.R3317C | Missense Mutation (SNP) | VAF 29/481 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as rs200696560; ClinVar: uncertain significance; called by muse, mutect2
- USP17L2 | c.1563C>A p.H521Q | Missense Mutation (SNP) | VAF 32/668 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV100414601, COSV100414652; called by muse, mutect2
- USP25 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as rs1052196375; called by muse, mutect2
- UTP15 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761103496, COSV57145916; called by muse, mutect2
- VNN1 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV63389436; called by muse, mutect2
- ZBTB16 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 66/429 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs772815592, COSV60099379; called by muse, mutect2, varscan2
- ZC4H2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62004652; called by muse, mutect2
- ZNF596 | c.224-2A>T p.X75_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | catalogued as rs1459794525; called by muse, mutect2
- ZNF831 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.388); catalogued as rs779936120, COSV64036999; called by muse, mutect2, varscan2
- ZXDB | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.653); catalogued as COSV66493078; called by muse, mutect2, varscan2
- ABCA12 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ABCA5 | c.2145C>G p.D715E | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ACAT1 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS17 | c.2029G>T p.D677Y | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY10 | c.1685C>A p.A562D | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ALK | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 38/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALMS1 | c.8563G>T p.G2855* | Nonsense Mutation (SNP) | VAF 32/355 reads (9%) | called by muse, mutect2
- ALPG | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2
- APOB | c.5234C>A p.S1745* | Nonsense Mutation (SNP) | VAF 50/231 reads (22%) | called by muse, mutect2, varscan2
- ARSF | c.1533G>T p.R511S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ASPA | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- ASXL2 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- ATMIN | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2A2 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 41/290 reads (14%) | called by muse, mutect2, varscan2
- BACH2 | c.1181A>G p.Q394R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- BCLAF3 | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- BDH2 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | called by mutect2, varscan2
- BICC1 | c.2410C>A p.R804S | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BRD3 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- BRIX1 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- BTBD11 | c.2227C>A p.H743N (on ENST00000280758 / NM_001018072.2; = p.H280N on NM_001017523.2) | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BTBD17 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- BTBD17 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- BTN1A1 | c.1247C>A p.A416E | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- C10orf71 | c.2698G>T p.G900C | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- C10orf90 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2
- C14orf180 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- C16orf82 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2orf16 | c.3356C>A p.P1119H | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C3orf70 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5orf58 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2
- C8B | c.669C>T p.T223= | Splice Region (SNP) | VAF 40/183 reads (22%) | called by mutect2, varscan2
- CA12 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 111/357 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CAB39 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1E | c.5530C>A p.P1844T | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CALCR | c.1336G>T p.A446S (on ENST00000649521 / NM_001164737.2; = p.A430S on NM_001742.4) | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CAMTA1 | c.2873C>A p.P958H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CARD11 | c.96G>T p.M32I | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CARMIL1 | c.1366G>T p.G456W | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- CASKIN1 | c.2923G>A p.G975S | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- CCDC102B | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CCT2 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CD1B | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CDC14C | c.500G>T p.G167V (on ENST00000428251; = p.G60V on NM_152627.3) | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR1 | c.3890A>T p.Q1297L | Missense Mutation (SNP) | VAF 104/334 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CEP131 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CEP295 | c.3372G>T p.Q1124H | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CFAP20DC | c.586A>T p.T196S (on ENST00000482387 / NM_001351530.2; = p.T71S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CFAP221 | c.2491A>G p.K831E | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CFTR | c.3368G>T p.G1123V | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, varscan2
- CHCHD5 | c.179A>C p.Q60P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CHPF | c.2042A>T p.N681I | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLASP1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLCN1 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 29/507 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CLEC4F | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CLIC3 | c.221A>T p.D74V | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLRN2 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2
- CLTCL1 | c.4211G>C p.C1404S | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CMAS | c.1122A>C p.E374D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- CMBL | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 74/227 reads (33%) | called by muse, varscan2
- COL18A1 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- COL18A1 | c.3469G>T p.G1157* (on ENST00000359759 / NM_130444.3; = p.G922* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 33/315 reads (10%) | called by muse, mutect2, varscan2
- COL1A2 | c.3917G>T p.S1306I | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A3 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- COX4I1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- CPED1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRACDL | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by mutect2, varscan2
- CRIP2 | c.468C>A p.C156* | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- CROCC | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 23/256 reads (9%) | called by muse, mutect2
- CSPG4 | c.1973C>A p.A658D | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CTNNA2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.088); called by muse, mutect2
- CUEDC2 | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CWC22 | c.2587G>T p.G863C | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.401); called by muse, mutect2
- DCC | c.3164-1G>T p.X1055_splice | Splice Site (SNP) | VAF 10/243 reads (4%) | called by muse, mutect2
- DDX60 | c.2787G>T p.E929D | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.244); called by muse, varscan2
- DNAAF1 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH2 | c.3070C>A p.L1024M | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DNAH5 | c.3538G>T p.E1180* | Nonsense Mutation (SNP) | VAF 160/365 reads (44%) | called by muse, mutect2, varscan2
- DNAI2 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNM1 | c.496A>T p.K166* | Nonsense Mutation (SNP) | VAF 97/329 reads (29%) | called by muse, mutect2, varscan2
- DNTT | c.89T>A p.I30N | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- DOCK7 | c.6116A>T p.E2039V (on ENST00000635253 / NM_001367561.1; = p.E2008V on NM_033407.3) | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP2 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DYNC2H1 | c.1865A>G p.H622R | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- DYNC2H1 | c.12064G>T p.G4022C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DYTN | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2
- DZIP1 | c.2308C>A p.P770T (on ENST00000347108; = p.P751T on NM_014934.5) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECPAS | c.3710A>T p.K1237I | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- EEF1A2 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- EEF1AKMT2 | c.674C>G p.A225G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EFTUD2 | c.1420del p.L474* | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel
- EGFL6 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- EGFLAM | c.2265C>A p.F755L | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- EIF2S2 | c.980_982dup p.Q327dup | In Frame Ins (INS) | VAF 16/94 reads (17%) | called by mutect2, pindel, varscan2
- EML6 | c.2123C>A p.A708E | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EMX1 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ENTPD5 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EOLA2 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHX2 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ETNPPL | c.147C>A p.Y49* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | called by muse, varscan2
- EXT1 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 213/713 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- F13B | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FAM120B | c.1939G>T p.V647F | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAM78A | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FASN | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FAT3 | c.6294A>T p.E2098D | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FCAR | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FGF12 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FOXD4L1 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 116/445 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- FZD6 | c.1359T>G p.H453Q | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- GABRA5 | c.986C>A p.A329D | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GABRQ | c.1782C>A p.F594L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GALR1 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GATA4 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 47/581 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2
- GDF10 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.43); called by muse, mutect2
- GJD4 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI3 | c.4138G>T p.V1380F | Missense Mutation (SNP) | VAF 122/837 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GNL3 | c.836T>C p.M279T | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- GOLGA8T | c.1790C>G p.P597R | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GPD1L | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- GPR142 | c.654G>T p.Q218H | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GPR174 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- GRIK4 | c.1946T>C p.M649T | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM5 | c.1379del p.G460Efs*9 | Frame Shift Del (DEL) | VAF 34/154 reads (22%) | called by mutect2, pindel, varscan2
- GRM8 | c.2596C>A p.Q866K | Missense Mutation (SNP) | VAF 52/443 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRPR | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- H1-5 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 60/408 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- HCN4 | c.3272C>A p.P1091Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, varscan2
- HEY2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HGF | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLCS | c.89A>T p.K30M | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HMCN2 | c.10396C>A p.L3466M | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPUL2 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXB5 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- HOXC12 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- HPS4 | c.707-8A>T | Splice Region (SNP) | VAF 64/334 reads (19%) | called by muse, mutect2, varscan2
- HPSE2 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2
- HUWE1 | c.2833G>T p.V945L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- HYAL4 | c.459G>T p.W153C | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2
- ICE1 | c.6402T>G p.D2134E | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- IGHV7-81 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 63/338 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV3D-11 | c.222G>T p.R74S | Missense Mutation (SNP) | VAF 73/500 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- IL1R2 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IL23R | c.1105A>T p.I369F | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2
- IL33 | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by mutect2, varscan2
- IL4I1 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- IMMP2L | c.249_253dup p.P85Qfs*11 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, pindel
- ING2 | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, varscan2
- INPP5D | c.3106G>T p.D1036Y (on ENST00000445964 / NM_001017915.3; = p.D1035Y on NM_005541.5) | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- INSRR | c.1229G>C p.G410A | Missense Mutation (SNP) | VAF 103/522 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ITLN2 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- JAKMIP2 | c.1930-2A>G p.X644_splice | Splice Site (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- KCNN3 | c.1862A>G p.Q621R (on ENST00000618040 / NM_001204087.1; = p.Q606R on NM_002249.6) | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.167); called by muse, mutect2
- KCNQ3 | c.544dup p.C182Lfs*102 | Frame Shift Ins (INS) | VAF 237/843 reads (28%) | called by mutect2, pindel, varscan2
- KCTD8 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5C | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- KDM8 | c.798+2T>C p.X266_splice | Splice Site (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- KERA | c.275A>C p.E92A | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF14 | c.4003G>C p.A1335P | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.36); called by muse, mutect2
- KIRREL2 | c.2009T>C p.F670S | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KMO | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2C | c.14272A>C p.K4758Q | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KRTAP10-9 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LAMA4 | c.3618G>T p.Q1206H (on ENST00000230538 / NM_001105206.3; = p.Q1199H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/429 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB1 | c.2632C>A p.P878T | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LAMB1 | c.1443C>A p.C481* | Nonsense Mutation (SNP) | VAF 47/221 reads (21%) | called by muse, mutect2, varscan2
- LAMC1 | c.4704G>T p.Q1568H | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- LDB3 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- LIG1 | c.1336del p.L446* | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | called by mutect2, pindel*, varscan2
- LOXL3 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPA | c.5121C>G p.I1707M | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- LRIT3 | c.1697G>A p.C566Y | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC55 | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRC66 | c.572T>G p.F191C | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRTM4 | c.440C>A p.T147K | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LTBP1 | c.2662C>A p.H888N (on ENST00000404816 / NM_206943.4; = p.H562N on NM_000627.4) | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LTBP1 | c.5083G>T p.G1695C (on ENST00000404816 / NM_206943.4; = p.G1369C on NM_000627.4) | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP3 | c.1594A>G p.T532A | Missense Mutation (SNP) | VAF 99/534 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- MAGEC1 | c.2920T>C p.Y974H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MAP2 | c.2076G>T p.R692S | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2
- MAP4K4 | c.3675G>C p.Q1225H (on ENST00000347699 / NM_001242559.2; = p.Q1151H on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAPK10 | c.1090G>T p.E364* (on ENST00000359221 / NM_001351625.2; = p.E402* on NM_002753.5) | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ME2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- MEGF10 | c.1534G>C p.G512R | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MTMR2 | c.756T>G p.D252E | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MUC16 | c.28498C>A p.L9500M | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- MUC2 | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- MXRA5 | c.1937G>T p.S646I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- MYH7 | c.5294T>A p.M1765K | Missense Mutation (SNP) | VAF 86/652 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYO3A | c.2203A>T p.N735Y | Missense Mutation (SNP) | VAF 29/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYO5B | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- MYO7B | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- MYOM2 | c.1534G>C p.G512R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2
- NCOA6 | c.1447G>T p.G483* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- NFASC | c.2471T>A p.L824* (on ENST00000339876 / NM_001378329.1; = p.V927E on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/190 reads (13%) | called by muse, varscan2
- NFKB2 | c.1227dup p.T410Hfs*96 | Frame Shift Ins (INS) | VAF 10/88 reads (11%) | called by pindel, varscan2
- NPTX1 | c.113A>T p.D38V | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- NTM | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- NUDCD1 | c.1497dup p.A500Cfs*13 | Frame Shift Ins (INS) | VAF 14/104 reads (13%) | called by pindel, varscan2
- NUDT21 | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- NYAP2 | c.1739G>A p.W580* | Nonsense Mutation (SNP) | VAF 44/388 reads (11%) | called by muse, mutect2, varscan2
- OCLN | c.808_811del p.K270Wfs*61 | Frame Shift Del (DEL) | VAF 48/368 reads (13%) | called by pindel, varscan2
- OR2L3 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2T6 | c.607T>A p.C203S | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4E2 | c.698G>C p.R233P | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- OR51V1 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.065); called by muse, mutect2
- OR5D18 | c.752T>A p.I251N | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR5M3 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- OR6F1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OTOF | c.2881C>A p.Q961K (on ENST00000272371 / NM_194248.3; = p.Q214K on NM_004802.4) | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- OTX1 | c.951G>T p.L317F | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- P3H1 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PADI2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PATJ | c.4360G>A p.G1454R | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- PBXIP1 | c.1388A>T p.K463M | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PCDH7 | c.2325C>A p.S775R | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDHB6 | c.2137A>T p.R713W | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, varscan2
- PCDHB6 | c.2138G>A p.R713K | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, varscan2
- PCYT1B | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN3 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PELP1 | c.1228A>T p.S410C | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PELP1 | c.1227G>T p.W409C | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by mutect2, varscan2
- PEX1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PGK2 | c.1012G>T p.G338W | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGR | c.2416C>A p.Q806K | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PHLDB2 | c.3734C>A p.A1245E (on ENST00000393925 / NM_001134439.2; = p.A1202E on NM_145753.2) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PIEZO2 | c.2570G>T p.R857M | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PITPNM3 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKHD1L1 | c.9347G>T p.G3116V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLEKHH1 | c.2166C>A p.D722E | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PLEKHS1 | c.391A>G p.I131V (on ENST00000369310 / NM_182601.1; = p.I137V on NM_024889.5) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLK1 | c.1696C>G p.L566V | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.264); called by muse, mutect2
- PLSCR2 | c.266A>G p.Y89C (on ENST00000497985 / NM_001199978.1; = p.Y16C on NM_020359.2) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); called by muse, mutect2
- POLA1 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- POM121L2 | c.245A>T p.N82I | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); called by muse, mutect2
- POM121L2 | c.244A>C p.N82H | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.85); called by muse, mutect2
- POSTN | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPFIBP2 | c.1358G>A p.S453N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPM1E | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PPP2R5C | c.1513A>T p.T505S | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- PRDM8 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PREX1 | c.3685G>T p.V1229L | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- PREX1 | c.3685-1G>T p.X1229_splice | Splice Site (SNP) | VAF 79/287 reads (28%) | called by muse, mutect2, varscan2
- PRSS22 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSME4 | c.2279G>T p.G760V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2
- PTK2 | c.1991G>T p.S664I | Missense Mutation (SNP) | VAF 128/410 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RASIP1 | c.2022G>T p.E674D | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RESF1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 39/202 reads (19%) | called by muse, mutect2, varscan2
- RET | c.2571G>C p.Q857H | Missense Mutation (SNP) | VAF 34/571 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RGS6 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RHPN1 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- RIMS2 | c.2684C>G p.S895C (on ENST00000666250 / NM_001348490.2; = p.S703C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIT2 | c.87_88delinsT p.G30Efs*7 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | called by pindel, varscan2*
- RNASE11 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF144A | c.688G>T p.G230* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- ROBO2 | c.2066C>G p.A689G | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RSC1A1 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- RTL9 | c.3693G>T p.E1231D | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RUFY4 | c.1525A>G p.R509G | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RUNDC3B | c.427A>T p.R143* | Nonsense Mutation (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- RUNX1 | c.500A>C p.K167T (on ENST00000344691 / NM_001001890.3; = p.K194T on NM_001754.5) | Missense Mutation (SNP) | VAF 17/354 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAMD9 | c.3406G>C p.E1136Q | Missense Mutation (SNP) | VAF 44/397 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SAMSN1 | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); called by muse, mutect2
- SATB2 | c.1269T>A p.N423K | Missense Mutation (SNP) | VAF 31/511 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2
- SAXO1 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCFD2 | c.787G>C p.A263P | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- SCN3A | c.2611C>A p.L871I | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SCN5A | c.4106G>T p.G1369V (on ENST00000333535 / NM_198056.3; = p.G1368V on NM_000335.5) | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SEH1L | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SEMA3D | c.709T>C p.W237R | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5B | c.736del p.E246Sfs*95 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- SERPINA1 | c.781A>T p.S261C | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SERPINB13 | c.1069T>A p.S357T | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- SGK2 | c.219C>T p.P73= | Splice Region (SNP) | VAF 25/175 reads (14%) | called by muse, mutect2, varscan2
- SHROOM3 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC11 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- SIRPB1 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 91/421 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SLC16A14 | c.902A>T p.Y301F | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SLC17A2 | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- SLC40A1 | c.1591G>T p.V531L | Missense Mutation (SNP) | VAF 47/403 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLC6A13 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC6A5 | c.2286A>T p.L762F | Missense Mutation (SNP) | VAF 37/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SLC9B2 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- SNAPC4 | c.1179G>T p.K393N | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SNTG1 | c.1093G>T p.G365W | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORT1 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2
- SOX3 | c.1183G>C p.G395R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP8 | c.505G>T p.V169L (on ENST00000361443 / NM_198956.4; = p.V187L on NM_182700.6) | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SPAG16 | c.1594-2A>T p.X532_splice | Splice Site (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2
- SPATA31A1 | c.1591A>C p.K531Q | Missense Mutation (SNP) | VAF 36/570 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SPNS3 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SPRR2A | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SPSB3 | c.209_211del p.F70del | In Frame Del (DEL) | VAF 10/110 reads (9%) | called by mutect2, pindel
- SPTBN4 | c.2432T>C p.L811P | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SREBF1 | c.2675A>T p.E892V | Missense Mutation (SNP) | VAF 47/604 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.267); called by muse, mutect2
- SRGAP1 | c.2068C>A p.H690N | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SRMS | c.1386C>A p.C462* | Nonsense Mutation (SNP) | VAF 37/155 reads (24%) | called by muse, mutect2, varscan2
- STAB2 | c.4409C>A p.T1470K | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- STK33 | c.786+1G>T p.X262_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- SUGCT | c.1216C>G p.Q406E (on ENST00000335693 / NM_001193313.2; = p.Q432E on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.124); called by muse, mutect2
- SYNE1 | c.2504A>T p.N835I (on ENST00000367255 / NM_182961.4; = p.N842I on NM_033071.3) | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SYTL1 | c.1190C>G p.P397R (on ENST00000543823; = p.P385R on NM_032872.3) | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- TAF2 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2
- TBC1D1 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- TCEA3 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- TGM1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- THADA | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2
- TMEM130 | c.893C>G p.A298G | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TMEM31 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TNRC6A | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS3 | c.517del p.M173* | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, varscan2
- TP53BP1 | c.1953A>T p.K651N | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TPH1 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- TRIB2 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIL | c.2274C>G p.D758E | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.339); called by muse, mutect2
- TRIM60 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM60 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRMT5 | c.1393A>T p.T465S | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TSBP1 | c.1174del p.Q392Rfs*2 (on ENST00000617061; = p.Q397Rfs*2 on NM_006781.5) | Frame Shift Del (DEL) | VAF 40/296 reads (14%) | called by mutect2, pindel, varscan2
- TSGA10IP | c.1184A>T p.Q395L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TTN | c.21020_21041del p.Y7007Ffs*55 (on ENST00000591111; = p.Y6080Ffs*55 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel
- TTN | c.7817dup p.E2608Rfs*26 (on ENST00000591111; = p.E2562Rfs*26 on NM_003319.4) | Frame Shift Ins (INS) | VAF 13/134 reads (10%) | called by mutect2, pindel, varscan2
- UBE2O | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- UBXN11 | c.883G>A p.E295K (on ENST00000374221 / NM_183008.2; = p.E262K on NM_145345.2) | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- UROS | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 46/638 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.07); called by muse, mutect2
- USP4 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- VWA2 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VWCE | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2
- VWDE | c.320T>A p.I107N | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WNT10A | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZMYND15 | c.1367G>T p.R456L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ZNF107 | c.1502G>T p.C501F | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF124 | c.1046A>T p.K349I (on ENST00000543802 / NM_001297568.1; = p.K287I on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZNF419 | c.1379G>C p.C460S | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF438 | c.1773G>T p.R591S | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ZNF469 | c.10727C>A p.P3576Q (on ENST00000437464; = p.P3604Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ZNF479 | c.497T>C p.F166S | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- ZNF541 | c.2403G>C p.Q801H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF627 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- ZNF713 | c.223G>C p.E75Q (on ENST00000633730 / NM_001366796.2; = p.E88Q on NM_182633.3) | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZNF787 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- ZNF91 | c.3221G>T p.R1074I | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ZNRF4 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ADAM18 | c.1695T>A p.A565= | Silent (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.222G>A p.V74= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs1234641905; called by muse, mutect2, varscan2
- ADARB1 | c.51G>A p.K17= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- ADGRG4 | c.6597G>T p.G2199= | Silent (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- AGMO | c.495C>G p.L165= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV61113707; called by muse, mutect2, varscan2
- AGRN | c.1479G>T p.A493= | Silent (SNP) | VAF 111/423 reads (26%) | called by muse, mutect2, varscan2
- AGXT | c.826C>T p.L276= | Silent (SNP) | VAF 44/347 reads (13%) | called by muse, mutect2, varscan2
- AHNAK | c.11694G>A p.V3898= | Silent (SNP) | VAF 21/315 reads (7%) | called by muse, mutect2
- AL031777.2 | c.39T>A p.A13= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2
- ALAD | c.561T>G p.L187= | Silent (SNP) | VAF 15/364 reads (4%) | called by muse, mutect2
- ALPG | c.567G>C p.S189= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs772670586, COSV54967400; called by muse, mutect2
- ANK2 | c.9417G>A p.R3139= | Silent (SNP) | VAF 56/454 reads (12%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2649C>T p.A883= (on ENST00000611781; = p.A827= on NM_052997.2) | Silent (SNP) | VAF 112/456 reads (25%) | catalogued as COSV100652725; called by muse, mutect2, varscan2
- ARID3C | c.928C>A p.R310= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- AUTS2 | c.2841G>A p.P947= | Silent (SNP) | VAF 68/306 reads (22%) | catalogued as rs1481928441, COSV100720004, COSV61388061; called by muse, mutect2, varscan2
- BAG6 | c.1746G>T p.V582= (on ENST00000676571; = p.V535= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- BTBD17 | c.216G>T p.A72= | Silent (SNP) | VAF 68/359 reads (19%) | catalogued as rs766568463, COSV64729610; called by muse, mutect2, varscan2
- C3orf38 | c.738T>C p.C246= | Silent (SNP) | VAF 9/223 reads (4%) | called by muse, mutect2
- CADM3 | c.963G>T p.P321= (on ENST00000368125 / NM_001127173.3; = p.P355= on NM_021189.5) | Silent (SNP) | VAF 63/291 reads (22%) | catalogued as rs753580284, COSV63676528, COSV63677532; called by muse, mutect2, varscan2
- CAMSAP1 | c.4119G>T p.V1373= | Silent (SNP) | VAF 55/190 reads (29%) | called by muse, mutect2, varscan2
- CCDC88C | c.3297A>G p.K1099= | Silent (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- CCNB1 | c.891G>T p.L297= | Silent (SNP) | VAF 66/226 reads (29%) | called by muse, mutect2, varscan2
- CCNT2 | c.1404G>T p.G468= | Silent (SNP) | VAF 24/177 reads (14%) | catalogued as rs1439380794; called by muse, varscan2
- CD109 | c.2403C>A p.A801= | Silent (SNP) | VAF 32/236 reads (14%) | called by muse, varscan2
- CD33 | c.588G>T p.V196= | Silent (SNP) | VAF 46/244 reads (19%) | called by muse, mutect2, varscan2
- CGA | c.312G>C p.T104= | Silent (SNP) | VAF 24/220 reads (11%) | called by muse, varscan2
- CHRM2 | c.117C>A p.I39= | Silent (SNP) | VAF 37/282 reads (13%) | catalogued as COSV57773475; called by muse, mutect2, varscan2
- CNOT1 | c.3561A>G p.S1187= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as rs1567399105; called by muse, mutect2
- CNTNAP4 | c.3148C>A p.R1050= | Silent (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- COL18A1 | c.3988C>A p.R1330= (on ENST00000359759 / NM_130444.3; = p.R1095= on NM_030582.4) | Silent (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2
- COL8A1 | c.1725C>T p.P575= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99658179; called by muse, mutect2, varscan2
- COPB2 | c.1374A>T p.I458= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- CPN2 | c.1551C>T p.Y517= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- CPXM2 | c.1608G>T p.T536= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs140485162; called by muse, mutect2, varscan2
- CSPG4 | c.168C>A p.S56= | Silent (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- CTSG | c.402G>A p.E134= | Silent (SNP) | VAF 49/364 reads (13%) | catalogued as rs759496539; called by muse, mutect2, varscan2
- DLX4 | c.309G>A p.P103= (on ENST00000240306 / NM_138281.3; = p.P31= on NM_001934.3) | Silent (SNP) | VAF 22/290 reads (8%) | catalogued as COSV99537583; called by muse, mutect2
- DSP | c.4278G>C p.V1426= | Silent (SNP) | VAF 36/430 reads (8%) | catalogued as rs766933517; called by muse, mutect2
- DYM | c.1182G>T p.V394= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- EEF1AKMT2 | c.675G>T p.A225= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- ESPNL | c.2475G>T p.R825= | Silent (SNP) | VAF 29/200 reads (15%) | called by muse, mutect2, varscan2
- ESRP2 | c.150C>A p.T50= | Silent (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- FAM181A | c.999G>T p.V333= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- FER1L6 | c.27G>A p.K9= | Silent (SNP) | VAF 62/239 reads (26%) | called by muse, mutect2, varscan2
- FLNC | c.2886C>A p.P962= | Silent (SNP) | VAF 148/585 reads (25%) | catalogued as COSV57949944; called by muse, mutect2, varscan2
- FNDC1 | c.3120G>T p.R1040= | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- FREM1 | c.2706A>T p.S902= | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- GALNT14 | c.426G>T p.L142= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- GBP2 | c.132G>A p.V44= | Silent (SNP) | VAF 10/173 reads (6%) | called by muse, mutect2
- GDAP1 | c.552A>T p.A184= | Silent (SNP) | VAF 47/474 reads (10%) | called by muse, mutect2, varscan2
- GPN2 | c.240C>T p.G80= | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- GRIA2 | c.1902C>A p.I634= | Silent (SNP) | VAF 26/236 reads (11%) | catalogued as COSV52382128; called by muse, varscan2
- GRID2 | c.2631C>A p.L877= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, varscan2
- GRIK1 | c.2193C>A p.A731= | Silent (SNP) | VAF 48/330 reads (15%) | called by muse, mutect2, varscan2
- HERC5 | c.2655G>T p.R885= | Silent (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- HMCN1 | c.14517G>T p.R4839= | Silent (SNP) | VAF 88/377 reads (23%) | catalogued as rs746607981; called by muse, mutect2, varscan2
- HOXC6 | c.78C>T p.L26= | Silent (SNP) | VAF 72/222 reads (32%) | called by muse, mutect2, varscan2
- HRG | c.939A>T p.P313= | Silent (SNP) | VAF 63/452 reads (14%) | called by muse, mutect2, varscan2
- HSPA12A | c.1953C>A p.T651= | Silent (SNP) | VAF 22/294 reads (7%) | catalogued as COSV65022809; called by muse, mutect2
- HTR5A | c.888C>G p.L296= | Silent (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- INHBA | c.723G>T p.R241= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV99637084; called by muse, varscan2
- INPP4B | c.1845C>T p.P615= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs376023009; called by muse, mutect2, varscan2
- IRX4 | c.1488C>T p.D496= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as rs1333692482, COSV51471681; called by muse, mutect2
- ITSN1 | c.2355T>A p.L785= | Silent (SNP) | VAF 19/165 reads (12%) | called by muse, mutect2, varscan2
- KANSL1 | c.33A>T p.A11= | Silent (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- KCNS2 | c.1209C>A p.V403= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV54637651, COSV54639290; called by muse, mutect2, varscan2
- KIF13B | c.2433C>T p.F811= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV101568711; called by muse, mutect2
- KMT2D | c.12000C>A p.G4000= | Silent (SNP) | VAF 204/669 reads (30%) | called by muse, mutect2, varscan2
- KRT10 | c.843C>A p.A281= | Silent (SNP) | VAF 103/463 reads (22%) | called by muse, mutect2, varscan2
- L1TD1 | c.237A>T p.A79= | Silent (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- LGALS9 | c.1002G>A p.R334= (on ENST00000395473 / NM_009587.3; = p.R302= on NM_002308.4) | Silent (SNP) | VAF 51/423 reads (12%) | catalogued as rs373192382, COSV100119463; called by muse, mutect2, varscan2
- LRRC43 | c.417C>T p.T139= | Silent (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- MED12L | c.945C>G p.A315= | Silent (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- MEF2C | c.1308A>T p.R436= | Silent (SNP) | VAF 41/301 reads (14%) | called by muse, mutect2, varscan2
- MGAM2 | c.2421C>T p.D807= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as rs1282029533; called by muse, mutect2, varscan2
- MROH2B | c.2547C>A p.G849= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as rs1268829035, COSV68188396; called by muse, mutect2, varscan2
- MS4A2 | c.114A>G p.L38= | Silent (SNP) | VAF 44/414 reads (11%) | catalogued as rs755082001; called by muse, mutect2
- MUC16 | c.25689C>A p.S8563= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV101202189; called by muse, mutect2, varscan2
- MUC22 | c.5131C>T p.L1711= | Silent (SNP) | VAF 42/268 reads (16%) | called by muse, mutect2, varscan2
- NANOGNB | c.408A>G p.S136= | Silent (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- NEURL1 | c.471G>T p.L157= | Silent (SNP) | VAF 60/338 reads (18%) | called by muse, mutect2, varscan2
- NLRP3 | c.1449G>A p.E483= | Silent (SNP) | VAF 71/329 reads (22%) | catalogued as rs749604905, COSV60224747; called by muse, mutect2, varscan2
- NLRP5 | c.525G>T p.V175= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- NPAP1 | c.2256A>T p.S752= | Silent (SNP) | VAF 40/202 reads (20%) | called by muse, mutect2, varscan2
- NR1D2 | c.1488C>T p.L496= | Silent (SNP) | VAF 14/221 reads (6%) | catalogued as rs1299978376; called by muse, mutect2
- OR14A16 | c.165C>A p.T55= | Silent (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- OR4K5 | c.945A>T p.S315= | Silent (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2
- OR5AC2 | c.336A>T p.T112= | Silent (SNP) | VAF 31/215 reads (14%) | called by muse, mutect2, varscan2
- OR5AC2 | c.768T>A p.T256= | Silent (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- OR5F1 | c.423C>T p.Y141= | Silent (SNP) | VAF 24/164 reads (15%) | called by muse, varscan2
- OR5L1 | c.348C>A p.A116= | Silent (SNP) | VAF 61/287 reads (21%) | catalogued as COSV100449962, COSV61732671; called by muse, varscan2
- OR6J1 | c.117G>T p.L39= | Silent (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1335C>A p.A445= | Silent (SNP) | VAF 83/480 reads (17%) | catalogued as COSV56482128; called by muse, mutect2, varscan2
- PDE8B | c.1524G>A p.L508= | Silent (SNP) | VAF 85/357 reads (24%) | called by muse, mutect2, varscan2
- PDS5A | c.300C>A p.I100= | Silent (SNP) | VAF 45/275 reads (16%) | catalogued as COSV57825429; called by muse, mutect2, varscan2
- PDZRN3 | c.3181C>T p.L1061= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV55214171; called by muse, varscan2
- PI4KB | c.2370G>A p.E790= (on ENST00000368873 / NM_001369623.1; = p.E802= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.5151T>A p.A1717= | Silent (SNP) | VAF 24/259 reads (9%) | called by muse, mutect2
- PKP2 | c.789G>A p.T263= | Silent (SNP) | VAF 27/279 reads (10%) | catalogued as rs760432217; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- PLXNA4 | c.5307C>A p.A1769= | Silent (SNP) | VAF 15/318 reads (5%) | called by muse, mutect2
- PRR30 | c.657G>T p.L219= | Silent (SNP) | VAF 13/154 reads (8%) | catalogued as COSV53204438; called by muse, mutect2
- PYGM | c.2145G>A p.R715= | Silent (SNP) | VAF 56/441 reads (13%) | catalogued as rs1359883709; called by muse, mutect2, varscan2
- RAP1B | c.228A>G p.Q76= | Silent (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- RELN | c.2352G>T p.T784= | Silent (SNP) | VAF 29/199 reads (15%) | catalogued as COSV58987333; called by muse, mutect2, varscan2
- RFPL1 | c.879G>A p.K293= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs748122700; called by muse, mutect2, varscan2
- RGS7 | c.921G>T p.L307= | Silent (SNP) | VAF 50/483 reads (10%) | called by muse, mutect2, varscan2
- RUNDC3B | c.1030T>C p.L344= | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- RYR1 | c.12552C>T p.G4184= | Silent (SNP) | VAF 54/207 reads (26%) | catalogued as rs775632796, COSV62094427; called by muse, mutect2, varscan2
- SCAF1 | c.2718A>T p.A906= | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- SCFD2 | c.948A>C p.A316= | Silent (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2, varscan2
- SCUBE1 | c.1041G>A p.L347= | Silent (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- SKAP2 | c.420G>T p.R140= | Silent (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- SNX19 | c.2385G>T p.V795= | Silent (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- TAF3 | c.2553G>T p.T851= | Silent (SNP) | VAF 27/182 reads (15%) | catalogued as rs774790162, COSV60203754; called by muse, mutect2, varscan2
- TANC2 | c.3807C>T p.Y1269= | Silent (SNP) | VAF 26/246 reads (11%) | catalogued as rs191181540, COSV67329279; called by muse, mutect2, varscan2
- TBC1D15 | c.1836A>G p.L612= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs147480184; called by muse, mutect2, varscan2
- TBX4 | c.651C>T p.H217= | Silent (SNP) | VAF 78/663 reads (12%) | catalogued as rs1369518331; called by muse, mutect2, varscan2
- TCF25 | c.1395G>T p.L465= | Silent (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- TEDC2 | c.438G>A p.T146= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs759039578; called by muse, mutect2, varscan2
- TKTL2 | c.1050C>A p.T350= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- TMEM199 | c.330G>T p.L110= | Silent (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2
- TMPRSS7 | c.1362T>A p.P454= (on ENST00000452346; = p.P328= on NM_001042575.2) | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as rs1384723685; called by muse, mutect2, varscan2
- TOP3A | c.369A>T p.P123= | Silent (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- TRPA1 | c.2658C>A p.L886= | Silent (SNP) | VAF 46/248 reads (19%) | called by muse, varscan2
- UNC5D | c.1899C>A p.I633= | Silent (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- USP29 | c.1404C>T p.S468= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs767667594; called by muse, mutect2, varscan2
- WDR49 | c.1029G>T p.G343= (on ENST00000308378 / NM_001366158.1; = p.G684= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/213 reads (16%) | catalogued as rs760451996, COSV100393235; called by muse, mutect2, varscan2
- YTHDC1 | c.1854A>T p.P618= (on ENST00000344157 / NM_001031732.4; = p.P600= on NM_133370.4) | Silent (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- ZBTB39 | c.1074G>T p.L358= | Silent (SNP) | VAF 91/250 reads (36%) | called by muse, mutect2, varscan2
- ZFAT | c.1878G>T p.T626= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs777603767, COSV64743557; called by muse, mutect2, varscan2
- ZNF99 | c.27G>C p.V9= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.174G>T p.G58= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- AC090151.1 | chr8:54699529 C>A | 3'Flank (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- AC099552.1 | n.281G>T | RNA (SNP) | VAF 21/213 reads (10%) | called by muse, mutect2, varscan2
- AC104078.1 | n.309C>G | RNA (SNP) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- ACTR3BP2 | n.874T>G | RNA (SNP) | VAF 17/191 reads (9%) | called by muse, mutect2
- ADAMTS18 | c.*30C>A | 3'UTR (SNP) | VAF 30/238 reads (13%) | called by muse, mutect2, varscan2
- ADGRA1 | c.256-385C>A | Intron (SNP) | VAF 18/478 reads (4%) | called by muse, mutect2
- AL353804.7 | chrX:73852333 C>G | 3'Flank (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- ALOX12B | c.651-131G>C | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-799+5368G>T | Intron (SNP) | VAF 28/245 reads (11%) | catalogued as rs782745180; called by muse, mutect2, varscan2
- ASIC2 | c.556-179638C>A | Intron (SNP) | VAF 48/172 reads (28%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.785+16T>A | Intron (SNP) | VAF 38/299 reads (13%) | called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57623080 C>T | 3'Flank (SNP) | VAF 54/203 reads (27%) | catalogued as rs1284294272; called by muse, mutect2, varscan2
- BST1 | chr4:15736069 G>T | 3'Flank (SNP) | VAF 14/203 reads (7%) | called by muse, mutect2
- C14orf132 | chr14:96091032 G>T | 3'Flank (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2
- C5orf38 | c.*181C>A | 3'UTR (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- CACNB2 | c.214-61028G>C | Intron (SNP) | VAF 22/298 reads (7%) | called by muse, mutect2
- CCDC190 | chr1:162853156 G>A | 3'Flank (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- CCDC40 | c.2711+23A>T | Intron (SNP) | VAF 91/400 reads (23%) | called by muse, mutect2, varscan2
- CD82 | c.*1G>T | 3'UTR (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93731520 T>C | 3'Flank (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- CPZ | c.121+19C>A | Intron (SNP) | VAF 19/162 reads (12%) | catalogued as COSV100248819; called by muse, mutect2, varscan2
- DCHS2 | n.1654T>A | RNA (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- DEFB119 | c.61+1275G>A | Intron (SNP) | VAF 110/472 reads (23%) | called by muse, mutect2, varscan2
- DLK1 | c.262+33C>T | Intron (SNP) | VAF 68/462 reads (15%) | catalogued as rs748713107; called by muse, mutect2, varscan2
- DOCK10 | c.124-15271G>T | Intron (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- DPY19L2 | c.1580+2966G>T | Intron (SNP) | VAF 35/142 reads (25%) | called by muse, varscan2
- EGFR | c.1207+26A>G | Intron (SNP) | VAF 33/241 reads (14%) | catalogued as rs1019795074; called by muse, mutect2, varscan2
- FAAP100 | c.1404-294G>T | Intron (SNP) | VAF 30/180 reads (17%) | called by muse, mutect2, varscan2
- FAM170A | c.*8G>T | 3'UTR (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- FMO9P | n.253A>G | RNA (SNP) | VAF 10/184 reads (5%) | catalogued as rs1557844380; called by muse, mutect2
- FUNDC2P2 | n.387C>T | RNA (SNP) | VAF 23/674 reads (3%) | called by muse, mutect2
- GRM1 | c.2661-7271G>T | Intron (SNP) | VAF 21/208 reads (10%) | catalogued as COSV51108724; called by muse, mutect2
- HES6 | c.81+19G>T | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- HES6 | c.81+18G>T | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- IGFN1 | c.1242-3308G>T | Intron (SNP) | VAF 47/325 reads (14%) | called by muse, varscan2
- IGKV1OR22-5 | n.188G>T | RNA (SNP) | VAF 17/364 reads (5%) | called by muse, mutect2
- IL16 | c.-129G>A | 5'UTR (SNP) | VAF 20/294 reads (7%) | catalogued as rs1285164371; called by muse, mutect2
- KCND3 | c.-36G>A | 5'UTR (SNP) | VAF 70/259 reads (27%) | catalogued as rs200106311; called by muse, mutect2, varscan2
- KCNJ2 | c.*12C>G | 3'UTR (SNP) | VAF 37/420 reads (9%) | called by muse, mutect2
- KDM5C | c.963+49A>G | Intron (SNP) | VAF 26/90 reads (29%) | catalogued as rs782679883; called by muse, varscan2
- KEL | c.-43G>A | 5'UTR (SNP) | VAF 74/292 reads (25%) | called by muse, mutect2, varscan2
- KRT8P11 | n.1280C>A | RNA (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- LGR6 | chr1:202189326 C>A | 5'Flank (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- LINC01565 | n.1181C>A | RNA (SNP) | VAF 35/213 reads (16%) | called by muse, varscan2
- LINC01588 | chr14:50010984 C>G | 5'Flank (SNP) | VAF 32/267 reads (12%) | called by muse, mutect2, varscan2
- MAML3 | c.468+18616G>T | Intron (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- MAST4 | c.675-67917A>C | Intron (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- MIR222 | n.75A>G | RNA (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- MIR873 | n.62C>T | RNA (SNP) | VAF 33/143 reads (23%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92950G>T | Intron (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- NBPF11 | c.-549+2385G>T | Intron (SNP) | VAF 128/558 reads (23%) | called by muse, mutect2, varscan2
- NLRP2 | c.2709-36G>T | Intron (SNP) | VAF 80/329 reads (24%) | called by muse, mutect2, varscan2
- PDPK1 | c.1344-2810T>G | Intron (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2
- PHF8 | c.*1112G>C | 3'UTR (SNP) | VAF 16/61 reads (26%) | catalogued as rs782032821; called by muse, mutect2, varscan2
- PPFIA2 | c.645+41G>T | Intron (SNP) | VAF 9/72 reads (13%) | called by mutect2, varscan2
- PSG3 | c.*28G>C | 3'UTR (SNP) | VAF 27/145 reads (19%) | catalogued as rs1434922934; called by muse, mutect2, varscan2
- RAPGEF4 | c.-77G>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- RBBP8NL | c.-19G>T | 5'UTR (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- RHOQ | c.-32G>A | 5'UTR (SNP) | VAF 12/44 reads (27%) | catalogued as rs1352487308; called by muse, varscan2
- RNU6-1178P | chr17:20895749 del C | 5'Flank (DEL) | VAF 42/201 reads (21%) | catalogued as COSV60003348; called by mutect2, pindel, varscan2
- RTEL1 | c.396-51G>T | Intron (SNP) | VAF 62/438 reads (14%) | called by muse, mutect2, varscan2
- SCML2P1 | n.1068C>G | RNA (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2, varscan2
- SETBP1 | c.540+7321G>T | Intron (SNP) | VAF 23/143 reads (16%) | catalogued as COSV99954349; called by muse, mutect2, varscan2
- SH3TC1 | c.173-36G>T | Intron (SNP) | VAF 23/281 reads (8%) | catalogued as rs1349825590; called by muse, mutect2
- SHH | c.301-129C>T | Intron (SNP) | VAF 8/80 reads (10%) | catalogued as rs1445263802; called by muse, mutect2
- SLC25A3 | c.645-149G>T | Intron (SNP) | VAF 73/279 reads (26%) | called by muse, mutect2, varscan2
- SLC6A2 | c.*31T>A | 3'UTR (SNP) | VAF 52/318 reads (16%) | called by muse, mutect2, varscan2
- SMU1 | c.-14G>T | 5'UTR (SNP) | VAF 29/155 reads (19%) | catalogued as rs1274577086; called by muse, mutect2, varscan2
- SNORD115-35 | n.33A>T | RNA (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- SPHKAP | c.-17C>A | 5'UTR (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2, varscan2
- SYT14 | c.*18C>G | 3'UTR (SNP) | VAF 92/768 reads (12%) | catalogued as rs1394726154; called by muse, mutect2, varscan2
- TBX19 | c.917-22C>G | Intron (SNP) | VAF 48/334 reads (14%) | catalogued as rs998656594; called by muse, varscan2
- TEX261 | c.70+73G>T | Intron (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- TLE5 | c.190-79T>C | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- UBALD1 | c.184-229G>A | Intron (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- UGT2B27P | n.1494C>A | RNA (SNP) | VAF 74/404 reads (18%) | called by muse, mutect2, varscan2
- UQCRB | c.*1259C>T | 3'UTR (SNP) | VAF 37/221 reads (17%) | called by muse, mutect2, varscan2
- USP6 | c.1079-106C>A | Intron (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- VAPB | c.*4237dup | 3'UTR (INS) | VAF 59/579 reads (10%) | catalogued as rs1208084317; called by mutect2, pindel
- VSIG10 | c.*31T>A | 3'UTR (SNP) | VAF 20/159 reads (13%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438311 C>A | 5'Flank (SNP) | VAF 29/250 reads (12%) | called by muse, mutect2, varscan2
- Z83844.2 | c.92+73G>T | Intron (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- ZBTB17 | c.1371+76C>T | Intron (SNP) | VAF 13/204 reads (6%) | catalogued as rs1194426850; called by muse, mutect2
- ZDHHC23 | c.1216+169T>C | Intron (SNP) | VAF 18/213 reads (8%) | called by muse, mutect2
- ZEB1 | c.58+43635G>T | Intron (SNP) | VAF 60/277 reads (22%) | called by muse, mutect2, varscan2
- ZNF14 | c.-20G>C | 5'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
